Gene-level copy-number profile of tumor specimen TCGA-DB-A75O-01A from TCGA case TCGA-DB-A75O, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 29.6 years (10,812 days).
Specimen TCGA-DB-A75O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.c48411f8-f406-449f-a617-5002772bcbe7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DB-A75O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aac584b5-e58f-4cdf-93c3-4fd654379dad

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 105; copy number 1: 5,511; copy number 2: 52,309; copy number 3: 1,842; copy number 5: 29; copy number 8: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DB-A75O-01A-11D-A32A-01): tumor purity 0.59, ploidy 3.91, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 105 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:20,070,250–21,094,714, 30 genes: KRR1P1, AL138688.2, LINC01072, GJA3, PPIAP28, LINC00556, GJB2, AL138688.1, GJB6, CRYL1, MIR4499, AL590096.1, IFT88, SLC35E1P1, RNU2-7P, AL161772.1, IL17D, AL512652.2, EEF1AKMT1, RANP8, AL512652.1, XPO4, CNOT4P1, HNRNPA1P30, PPIAP27, RPSAP54, LATS2, LATS2-AS1, RNU4-9P, RPS12P23.
- chr13:23,134,174–26,222,314, 75 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 52 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:53,377,839–54,295,272, 2 genes, copy number 5–8 (within-gene range 3–8): AC058822.1, LNX1.
- chr4:53,575,713–55,905,086, 50 genes, copy number 5–8: AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1.

Autosomal genes at a single copy (total copy number 1): 3,124. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
